Surgical pathology report (de-identified scan), TCGA case TCGA-32-1980, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-1980-01A (Primary Tumor).

[page 1 of 2]
NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

Right temporal brain tumor

GBM
CONTROL

CLINICAL DIAGNOSIS:

Right temporal brain tumor

TCGA-32-1980

GROSS DESCRIPTION:

Received fresh for frozen section labeled with the patient's name and "right temporal brain tumor" are multiple fragments of tan soft tissue aggregating to 1.3 x 0.1 x 0.8 cm. A smear is made. Entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

GLIOBLASTOMA.

Tissue submitted for frozen is subsequently submitted for permanent in one cassette.

MICROSCOPIC DESCRIPTION:

Permanent sections of the frozen section specimen demonstrates a high grade glial neoplasm that diffusely infiltrates parenchyma. There are large areas of tumor necrosis, sometimes with pseudopalisading. The tumor cells resemble moderately atypical fibrillary and occasionally gemistocytic astrocytes. Microvascular proliferation is also seen. Scattered mitotic figures are noted.

DIAGNOSIS:

(PROVISIONAL)

RIGHT TEMPORAL BRAIN TUMOR, FROZEN SECTION BIOPSY:

GLIOBLASTOMA, PENDING REVIEW OF ADDITIONAL TISSUE.

ADDENDUM NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

1. Please see previous report.
2. Right temporal lobe and tumor
3. Intratumor hematoma

ADDENDUM GROSS DESCRIPTION:

1. Please see previous report.
2. Received in formalin labeled with the patient's name and "right temporal lobe and brain tumor" are multiple portions of tan-gray brain aggregating to 4.5 x 4.0 x 1.8 cm. Representative sections are submitted in three cassettes.
3. Received in formalin labeled with the patient's name and "intratumor hematoma" is a 2.0 x 1.8 x 1.0 cm tan-red blood clot. The specimen is entirely submitted in one cassette.

ADDENDUM DIAGNOSIS:

2. Sections, again, demonstrate a high grade glial neoplasm consistent with glioblastoma. The tumor demonstrates extensive necrosis. At the edges, there is infiltration into the parenchyma. Microvascular proliferation and mitotic figures are also seen.
3. Sections consist almost entirely of acute blood clot. A thin rim of tumor cells and reactive blood vessels is also seen.

ADDENDUM #2 NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

[page 2 of 2]
ADDENDUM #2 NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

Fewer than 10% of cells overall demonstrate immunoreactivity for MGMT. Tumor cells immunoreactivity is limited to perinecrotic areas.

ADDENDUM DIAGNOSIS:

- 1, 2. RIGHT TEMPORAL BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA
- TUMOR CELLS NEGATIVE FOR MGMT EXPRESSION.

Source: NCI Genomic Data Commons file c7a2471f-0799-42f6-9a22-69fc59c37156 (TCGA-32-1980.7660F091-9B09-4DFA-9530-BDB57E930938.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).